Somatic mutation profile of tumor specimen TCGA-BJ-A0ZG-01A (aliquot TCGA-BJ-A0ZG-01A-11D-A10S-08) from TCGA case TCGA-BJ-A0ZG, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 80.4 years (29,375 days).
Specimen TCGA-BJ-A0ZG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe6d9eac-b5bf-46c7-917d-b3f00fe36493.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A0ZG-10A (Blood Derived Normal), aliquot TCGA-BJ-A0ZG-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/983e3fc7-0050-42ff-a756-8c3faea1d36f

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 67/112 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63309275, COSV63309367; called by muse, mutect2, varscan2
- CLIP3 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs368502619; called by muse, mutect2, varscan2
- MYO5C | c.5204A>G p.K1735R | Missense Mutation (SNP) | VAF 25/272 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.277); catalogued as rs746042613, COSV55899953; called by muse, mutect2
- PPP1R3B | c.754T>A p.L252M | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1563124709, COSV60099768; called by muse, mutect2, varscan2
- SMUG1 | c.398A>T p.Q133L | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV54539918; called by muse, mutect2
- TRAV9-2 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs758191408; called by muse, mutect2, varscan2
- KRTAP13-4 | c.387C>A p.S129= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV61879633; called by muse, mutect2
- TRMT5 | c.1293T>G p.V431= | Silent (SNP) | VAF 10/174 reads (6%) | catalogued as COSV54204013; called by muse, mutect2
